Somatic mutation profile of tumor specimen TARGET-20-PANSBH-04A (aliquot TARGET-20-PANSBH-04A-01D) from TARGET case TARGET-20-PANSBH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.3 years (491 days).
Specimen TARGET-20-PANSBH-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 261a3bda-f09e-46dc-8ecd-9091c6775e88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANSBH-14A (Bone Marrow Normal), aliquot TARGET-20-PANSBH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b429fcc1-2b59-4b4c-a472-fb27758f6249

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRWD1 | c.2969_2972del p.N990Rfs*17 | Frame Shift Del (DEL) | VAF 47/171 reads (27%) | called by mutect2, pindel, varscan2
- TFDP1 | c.1003A>G p.T335A | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.514); called by muse, varscan2
- THOC1 | c.1962G>C p.E654D | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2
- ADGRD2 | c.2256A>G p.T752= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as COSV58341095; called by muse, mutect2, varscan2
- KCNH2 | c.1284G>A p.S428= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs371864051; called by muse, mutect2, varscan2
- PARP4 | c.2583A>G p.Q861= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs765767892; called by muse, mutect2, varscan2
